CCDI case PBCNSL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Odontogenic Tumors; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/7da8b186-a77c-4057-9014-a6daef9f6f70

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Odontogenic carcinosarcoma: ICD-O-3 morphology code: 9342/3; Tissue or organ of origin: Maxillary sinus; Age at diagnosis: 9.8 years (3,597 days).

Biospecimens (3 samples)
- Sample 0DWGJ5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWGJJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWGK5: Tissue type: Tumor; Specimen type: Solid Tissue.
